CPTAC case C3L-00143 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8f5fa81-4478-456f-bea3-fba6d48e5b11

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 69.6 years (25,407 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,708 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,708 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 19; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 357 days; Disease response: Tumor Free.
- Days to follow up: 675 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,053 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,409 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,708 days (4.7 years); Disease response: Tumor Free.
- Days to follow up: 1,708 days (4.7 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 99 kg; Height: 170 cm; BMI: 34.26; Comorbidities: Arthritis.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 1; Cigarettes per day: 10; Tobacco smoking onset year: 1964; Tobacco smoking quit year: 1966; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00143-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 271 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00143-21: Section location: anterior and posterior; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3L-00143-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00143-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
